TCGA case TCGA-24-0982 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/206ce0ed-36a4-47ab-ac8e-f6fca6ac5c18

Demographics
Sex at birth: female; Race: white; Age at index: 77 years; Vital status: Dead; Days to death: 679 days (1.9 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 77.2 years (28,201 days); Year of diagnosis: 2003; Method of diagnosis: Cytology; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 13 days; Days to treatment end: 125 days; Number of cycles: 6; Treatment dose: 4,090 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 13 days; Days to treatment end: 125 days; Number of cycles: 6; Treatment dose: 1,966 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 251 days; Days to treatment end: 321 days; Number of cycles: 4; Treatment dose: 39 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Recurrent Disease; Days to treatment start: 251 days; Days to treatment end: 321 days; Number of cycles: 4; Treatment dose: 390 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 341 days; Days to treatment end: 474 days (1.3 years); Number of cycles: 5; Treatment dose: 24,798 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 341 days; Days to treatment end: 474 days (1.3 years); Number of cycles: 5; Treatment dose: 388 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 488 days (1.3 years); Days to treatment end: 615 days (1.7 years); Number of cycles: 7; Treatment dose: 3,800 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 488 days (1.3 years); Days to treatment end: 615 days (1.7 years); Number of cycles: 7; Treatment dose: 2,276 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 77.6 years (28,354 days); Days to diagnosis: 153 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 153 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 153 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 679 days (1.9 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-0982-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.8.
  Slide TCGA-24-0982-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25.
  Slide TCGA-24-0982-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 35.
- Sample TCGA-24-0982-10C: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid).
- Drug treatment 1: Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 5: Pharmaceutical therapy drug name: Navelbine.
- Drug treatment 7: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 679 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 679 days; disease-free interval: event (new tumor event after initially disease-free), 153 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 153 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-0982-01A-01D-0428-01): tumor purity 0.75, ploidy 2.86, whole-genome doublings 1.
